Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A548, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A548-01A (Primary Tumor).

[page 1 of 6]
ICD-0-3
Adenocarcinoma,
Endometrioid, NOS
8380/3
Site: Endometrium, C54.1
12/13/12 gdw

Diagnosis:

A: Uterus and cervix, bilateral ovaries and right fallopian tube, hysterectomy and bilateral oophorectomy, right salpingectomy

Location of tumor: anterior and posterior endometrium extending into anterior and posterior lower uterine segment and involving mucosa of posterior endocervix

Histologic type: endometrioid adenocarcinoma

Histologic grade (FIGO): 1

Size: 6.3 x 5.8 x 1.8 cm

Extent of invasion: non-invasive

Myometrial invasion: Non-invasive

Serosal involvement: not identified

Lower uterine segment involvement: present involving mucosa of anterior and posterior lower uterine segment

Cervical involvement: present involving mucosa of posterior endocervix. No cervical stromal invasion is identified.

Adnexal involvement (see below): not identified

Other sites: not applicable

Cervical margin and distance: widely negative (>2 cm from ectocervix margin by light microscopy)

Lymphovascular space invasion: not identified

Regional lymph nodes: -12 lymph nodes, negative for metastatic carcinoma

[page 2 of 6]
(0/12), see additional sections

Other pathologic findings:

- Uninvolved cervix with Nabothian cyst, hyper- and parakeratosis and acute and chronic cervicitis
- Leiomyoma with hyalinization , size ranging from 4 mm to 3.2 cm
- Adenomyosis with involvement by carcinoma (see comment)
- Scant uterine serosal adhesions
- Background atrophic endometrium

AJCC Pathologic Stage: pT1a pN0

FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovary, right, oophorectomy:

- Atrophic with surface inclusion glands and cysts, and scant adhesions
- No malignancy identified

Ovary, left, oophorectomy:

- Atrophic with endosalpingiosis, Leydig cell hyperplasia and scant adhesions
- No malignancy identified

Fallopian tube, right, salpingectomy:

- No significant pathologic abnormality

B: Lymph nodes, left pelvic, regional resection

- Two lymph nodes, one with endosalpingiosis
- No metastatic carcinoma identified (0/2)

C: Lymph nodes, right pelvic, regional resection

- Ten lymph nodes, one with endosalpingiosis, negative for metastatic carcinoma
- (0/10)

Comment:

Immunohistochemistry (CD10) is performed on A8 and demonstrates endometrial

[page 3 of 6]
glands and stroma within adenomyosis involved by carcinoma. No invasive carcinoma is identified.

Clinical History:

-year-old with endometrial cancer.

Gross Description:

Specimen A is received in one appropriately labeled container, additionally labeled "uterus, tube, ovaries, cervix."

Adnexa: present; left and right ovaries, right tube; left tube is absent

Weight: 170 grams

Shape: pyriform

Dimensions:

height: 9.6 cm

anterior to posterior width: 5.1 cm

breadth at fundus: 6.3 cm

Serosa: pink/tan, smooth and glistening

Cervix:

ectocervix: pink/white and smooth

endocervix: tan, smooth with surface adherent mass that is 0.6 cm from the

external os

length of endocervical canal: 1.8 cm

Endomyometrium:

length of endometrial cavity: 4.2 cm

width of endometrial cavity at fundus: 3.6 cm

tumor findings:

dimensions: 6.3 x 5.8 x 1.8 cm (protruding into the cavity)

appearance: soft rubbery tan, smooth and fungating

location and extent: The mass occupies approximately 75% of the endometrium, extends into the lower uterine segment, and into the anterior and posterior endocervical canal by 1.0 cm.

myometrial invasion: No apparent invasion.

thickness of myometrial wall at deepest gross invasion: 1.5 cm

other findings or comments: The uninvolved endometrium is tan, smooth, less

than 0.1 cm and the myometrium is pink/tan,

trabeculated with three homogeneous white whorled rubbery

[page 4 of 6]
nodules ranging
from 0.4 cm in greatest dimension up to 3.2
x 2.0 x 2.0 cm in greatest dimension, all of which bulge on cut
section.

Adnexa:

Right ovary:

dimensions: 2.2 x 1.5 x 1.0 cm

external surface: unremarkable

cut surface: unremarkable

Right fallopian tube:

dimensions: 4.3 cm long x 0.5 cm in diameter

other findings: unremarkable

Left ovary:

dimensions: 3.2 x 1.3 x 1.3 cm

external surface: unremarkable

cut surface: unremarkable

Left fallopian tube: n/a

Lymph nodes: none

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: Tumor given to
Tumor
Procurement foundation.

Block Summary:

A1 - anterior cervix

A2 - perpendicular of anterior lower uterine segment

A3,A4 - each contains full thickness anterior corpus, A4
contains intramural
nodule

A5 - posterior cervix

A6 - perpendicular of posterior lower uterine segment

A7,A8 - posterior corpus, full thickness, bisected

A9 - mass with uninvolved endometrium

A10 - intramural nodule

A11 - left ovary

A12 - right ovary

A13 - right fallopian tube

A14 - right fimbria, longitudinally sectioned

[page 5 of 6]
Specimen B is received in a formalin-filled container labeled "left pelvic lymph node" and consists of a 3.0 x 1.7 x 0.6 cm portion of adipose tissue that is bisected for lymph node candidates. Three lymph nodes are identified ranging from 0.3 cm in greatest dimension up to 1.5 x 1.0 x 1.0 cm in greatest dimension. The largest node has a speckled gray/white cut surface.

Block Summary:

B1 - two lymph nodes
B2 - one lymph node, serially sectioned
B3-B4 - remainder of specimen for potential lymph node candidates,

Specimen C is received in a formalin-filled container labeled "right pelvic lymph node" and consists of two fragments of adipose tissue (5.1 x 2.5 x 1.2 cm) in aggregate that are bisected for lymph node candidates. Eight lymph nodes are identified ranging from 0.5 cm in greatest dimension up to 3.2 x 1.7 x 0.9 cm in greatest dimension. Three of the lymph nodes have a gray/white speckled cut surface.

Block Summary:

C1 - two lymph nodes, each bisected, one inked blue, the non inked lymph node has the gray/white speckled cut surface
C2-C3 - one lymph node, serially sectioned, containing gray/white speckled cut surface
C4-C6 - one lymph node, serially sectioned, containing gray/white speckled cut surface
C7 - four lymph nodes
C8-C9 - remainder of specimen for potential lymph node candidates,

For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative

[page 6 of 6]
controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the Anatomic Pathology Department . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Reviewed Initials	Date Reviewed	

11/24/12

Source: NCI Genomic Data Commons file cc481015-1539-4ea7-9dad-c1692dae5219 (TCGA-EY-A548.A9ACF7BF-BB91-4B56-A398-C7A0FD473FC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).